Somatic mutation profile of tumor specimen TCGA-G3-A25Z-01A (aliquot TCGA-G3-A25Z-01A-11D-A16V-10) from TCGA case TCGA-G3-A25Z, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.9 years (21,509 days).
Specimen TCGA-G3-A25Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4956d118-4a9c-45cf-9e49-08ca5259c0f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A25Z-10A (Blood Derived Normal), aliquot TCGA-G3-A25Z-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c594efa-86e5-40b9-a350-f838441fff50

The open-access MAF lists 78 somatic variants for this specimen: 60 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 17, Frame Shift Del 3, Splice Region 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 33/57 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4841G>A p.G1614E (on ENST00000272895 / NM_173076.3; = p.G1296E on NM_015657.3) | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55971502, COSV55972486; called by muse, varscan2
- ABCA13 | c.11985G>T p.R3995S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV71292838; called by muse, mutect2, varscan2
- ASIC3 | c.534G>A p.T178= | Splice Region (SNP) | VAF 7/15 reads (47%) | catalogued as rs754745451, COSV52504774; called by muse, mutect2, varscan2
- ATP1A3 | c.767C>T p.T256M (on ENST00000545399 / NM_001256214.2; = p.T243M on NM_152296.5) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV57487559; called by muse, mutect2, varscan2
- BRAP | c.1246C>G p.L416V | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59538158; called by muse, mutect2, varscan2
- CAPSL | c.221T>A p.V74D | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV68439187; called by muse, mutect2, varscan2
- CDH8 | c.694A>G p.M232V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs376133486; called by muse, mutect2, varscan2
- CEP350 | c.8747T>C p.V2916A | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV62608255; called by muse, mutect2, varscan2
- CFAP20DC | c.884G>A p.R295Q (on ENST00000482387 / NM_001351530.2; = p.R170Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.18); catalogued as rs751925163, COSV55925656; called by muse, mutect2, varscan2
- CHD5 | c.2555T>A p.L852H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52422428; called by muse, mutect2, varscan2
- CTNNB1 | c.1213C>T p.L405F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62713382; called by muse, mutect2, varscan2
- DHRS9 | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV59141143; called by muse, mutect2, varscan2
- ENGASE | c.873G>T p.R291S | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.338); catalogued as COSV56137230; called by muse, mutect2, varscan2
- EP400 | c.7211A>G p.N2404S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as rs138179572; called by muse, varscan2
- EPHA6 | c.2180T>C p.I727T (on ENST00000389672 / NM_001080448.3; = p.I119T on NM_173655.4) | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67589043, COSV67597684; called by muse, mutect2, varscan2
- FAM193A | c.2556G>T p.L852F | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61197322; called by muse, mutect2, varscan2
- GH2 | c.554A>C p.N185T | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60427554; called by muse, mutect2
- GPHN | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59489681; called by muse, mutect2
- HERC2 | c.5829C>A p.D1943E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.956); catalogued as COSV55343345; called by muse, mutect2, varscan2
- HLA-A | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as CP995093, COSV100954534, COSV65141421; called by mutect2, varscan2
- HUNK | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352771277, COSV54226320; called by muse, mutect2, varscan2
- KLK11 | c.32A>G p.K11R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.099); catalogued as COSV51578570; called by muse, mutect2, varscan2
- LARGE2 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs974538917, COSV57658595; called by muse, mutect2, varscan2
- LPIN3 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as rs376739657; called by mutect2, varscan2
- MED12 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.323); catalogued as COSV61349633, COSV61351832; called by muse, mutect2, varscan2
- MEGF11 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.434); catalogued as COSV56558460; called by muse, mutect2, varscan2
- MGAT3 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV57867714; called by muse, mutect2, varscan2
- MYO9B | c.5498C>T p.A1833V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV68282006; called by muse, mutect2, varscan2
- NBEA | c.4739G>A p.R1580H | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs986998229, COSV59793708; called by muse, mutect2, varscan2
- NMBR | c.386T>G p.V129G | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57802837; called by muse, mutect2, varscan2
- OCRL | c.2293C>T p.L765F | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT tolerated (0.97); PolyPhen benign (0.04); catalogued as COSV63981612; called by muse, mutect2, varscan2
- OR5I1 | c.661T>C p.F221L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV56888636; called by muse, varscan2
- PGBD1 | c.1425G>T p.R475S | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV52555469; called by muse, mutect2, varscan2
- PIK3C2B | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs375951229; called by muse, mutect2, varscan2
- PLA2G6 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.347); catalogued as rs374007706; called by muse, mutect2, varscan2
- POLR2B | c.400A>G p.K134E | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV58902211; called by muse, mutect2, varscan2
- PPARA | c.511A>C p.I171L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV53080785; called by muse, mutect2, varscan2
- ROBO2 | c.2281G>T p.D761Y | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100170496, COSV59901818; called by muse, varscan2
- RP1L1 | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV66758858; called by muse, mutect2, varscan2
- RTN4 | c.619A>G p.M207V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV58272259; called by muse, mutect2
- RTN4 | c.617A>C p.N206T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58272279; called by muse, mutect2
- SLC10A1 | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs745341758, COSV53683644; called by muse, mutect2, varscan2
- SLC39A10 | c.2279C>A p.T760K | Missense Mutation (SNP) | VAF 140/292 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62768497, COSV62769015; called by muse, mutect2, varscan2
- STAB1 | c.3881G>T p.S1294I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV58741372; called by muse, mutect2, varscan2
- SUN1 | c.2155C>T p.L719F (on ENST00000405266 / NM_001367651.1; = p.L599F on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67451466; called by muse, mutect2, varscan2
- TATDN2 | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV55053549; called by muse, mutect2, varscan2
- TNN | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV53421489; called by muse, mutect2, varscan2
- TRAF6 | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 110/323 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.114); catalogued as COSV61923376; called by muse, mutect2, varscan2
- YES1 | c.656A>G p.N219S | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs557201481, COSV58852071; called by muse, mutect2, varscan2
- ZNF10 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV50214110; called by muse, mutect2, varscan2
- ZNF248 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV61998282; called by muse, mutect2, varscan2
- ZNF318 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs762724055, COSV58934536; called by muse, mutect2, varscan2
- ZNF91 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.984); catalogued as COSV56090501; called by muse, mutect2, varscan2
- ABCB1 | c.246del p.G83Efs*3 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel
- INTS10 | c.881dup p.Y294* | Nonsense Mutation (INS) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- KRTAP10-12 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- LILRB3 | c.44T>A p.L15Q | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- MRPL11 | c.301del p.A101Pfs*12 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- PTPN3 | c.2303del p.G768Afs*34 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- DPYSL4 | c.1641T>C p.D547= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs368616410; called by muse, mutect2, varscan2
- GPR34 | c.255A>G p.K85= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as COSV59373245; called by muse, mutect2, varscan2
- IGHV4-34 | c.45C>T p.L15= | Silent (SNP) | VAF 10/248 reads (4%) | catalogued as rs878928890; called by muse, mutect2
- IKBKE | c.402C>T p.R134= | Silent (SNP) | VAF 31/50 reads (62%) | catalogued as rs782809498, COSV65625649; called by muse, mutect2, varscan2
- KIAA1549L | c.5214G>A p.Q1738= (on ENST00000321505; = p.Q2035= on NM_012194.3) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV58594800; called by muse, mutect2, varscan2
- MUC16 | c.36531C>T p.G12177= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV67484610; called by muse, mutect2, varscan2
- NOVA1 | c.1353T>A p.T451= | Silent (SNP) | VAF 89/241 reads (37%) | catalogued as rs1439241916, COSV57484861; called by muse, mutect2, varscan2
- PCSK2 | c.159C>T p.H53= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs752064526, COSV52735471; called by muse, mutect2, varscan2
- POMP | c.219A>G p.L73= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs560145213, COSV66481924; called by muse, mutect2, varscan2
- RBM22 | c.939A>G p.K313= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV52272784; called by muse, mutect2, varscan2
- SLC12A1 | c.3270T>C p.N1090= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV66798435; called by muse, mutect2, varscan2
- SLC35A4 | c.867C>A p.V289= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs779439182, COSV60053755; called by muse, mutect2, varscan2
- SLC35G5 | c.690G>A p.G230= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV55314685; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.108G>A p.R36= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as rs267604247, COSV59529288; called by muse, mutect2, varscan2
- TOR2A | c.813C>T p.C271= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs370306195, COSV60161864; called by muse, mutect2, varscan2
- TTN | c.2826A>G p.P942= (on ENST00000591111; = p.P896= on NM_003319.4) | Silent (SNP) | VAF 67/143 reads (47%) | catalogued as COSV60109622; called by muse, mutect2, varscan2
- WWP2 | c.1623C>T p.R541= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV63126803; called by muse, mutect2, varscan2
- USH1C | c.1285-7463T>C | Intron (SNP) | VAF 16/79 reads (20%) | catalogued as COSV50029810; called by muse, mutect2, varscan2
